Somatic mutation profile of tumor specimen TCGA-DU-7292-01A (aliquot TCGA-DU-7292-01A-11D-2024-08) from TCGA case TCGA-DU-7292, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 69.2 years (25,266 days).
Specimen TCGA-DU-7292-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1616f9e-d233-4997-859d-b46b718c8db5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7292-10A (Blood Derived Normal), aliquot TCGA-DU-7292-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bab6de87-a1ba-46b8-b0f6-5f745dd9bab1

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 4, Intron 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 968/1225 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV51785413, COSV51800797; called by muse, mutect2, varscan2
- ADAMTS3 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV54391723; called by muse, mutect2, varscan2
- ADCY10 | c.4283T>A p.I1428N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV63240940; called by muse, mutect2, varscan2
- AL121899.2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs140423684, COSV101198425; called by muse, mutect2, varscan2
- ANXA1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57411306; called by muse, varscan2
- ARHGAP35 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754987943, COSV68331405; called by muse, mutect2, varscan2
- ASNS | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51552387; called by muse, mutect2, varscan2
- CLPSL1 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65814904; called by muse, mutect2, varscan2
- DDX4 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs374972771; called by muse, mutect2, varscan2
- EEF1A2 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.923); catalogued as COSV53206160; called by muse, mutect2
- ENAM | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs769115693, COSV68535985, COSV68537216; called by muse, mutect2, varscan2
- FER1L6 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 52/143 reads (36%) | catalogued as rs371608205; called by muse, mutect2, varscan2
- G6PC | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1470923557, COSV53831043; called by muse, mutect2, varscan2
- GRM4 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); catalogued as rs376358373; called by muse, mutect2, varscan2
- IRAG1 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773760936, COSV70210927; called by muse, mutect2, varscan2
- JAM2 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as COSV57257534; called by muse, mutect2, varscan2
- MTRR | c.371G>A p.G124D (on ENST00000264668; = p.G97D on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52942225; called by muse, mutect2, varscan2
- MYH3 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56865092; called by muse, mutect2, varscan2
- OTOA | c.707C>G p.T236S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV53754541; called by muse, mutect2, varscan2
- PCDHA5 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65352453; called by muse, mutect2, varscan2
- PCDHB4 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52022492; called by muse, mutect2, varscan2
- PIP4K2C | c.513G>A p.Q171= | Splice Region (SNP) | VAF 42/109 reads (39%) | catalogued as COSV61606157; called by muse, mutect2, varscan2
- POF1B | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV53134283; called by muse, mutect2
- SAMD14 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs551801846, COSV53309513; called by muse, mutect2, varscan2
- SEC24D | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54879907; called by muse, mutect2, varscan2
- SLITRK6 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV68389749; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3262G>A p.G1088S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs201237928, COSV64101103; called by muse, mutect2, varscan2
- TRPA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV51561972; called by muse, mutect2, varscan2
- WASF3 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1191996867, COSV58966068; called by muse, mutect2, varscan2
- WIF1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs572530696, COSV54131155, COSV99683195; called by muse, mutect2, varscan2
- ZNF333 | c.875A>C p.E292A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV52886173; called by muse, mutect2, varscan2
- CLCN3 | c.192C>T p.S64= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV61627136; called by muse, mutect2, varscan2
- FRMPD4 | c.3459C>T p.D1153= | Silent (SNP) | VAF 89/123 reads (72%) | catalogued as rs1427946992, COSV66215045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYB1 | c.610C>T p.L204= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV60946646; called by muse, mutect2, varscan2
- GCNT1 | c.567G>A p.S189= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs546314870, COSV65057751; called by muse, mutect2, varscan2
- GPRC5C | c.930C>T p.Y310= (on ENST00000652232; = p.Y265= on NM_018653.4) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs760203671, COSV61236983; called by muse, mutect2, varscan2
- HGD | c.807C>T p.H269= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs758567130, COSV52198233; called by muse, mutect2, varscan2
- NUMA1 | c.3021G>A p.A1007= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs752250707, COSV61183250; called by muse, mutect2, varscan2
- SLC19A1 | c.727C>A p.R243= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV60754645, COSV60755356; called by muse, mutect2, varscan2
- TNNI1 | c.52C>T p.L18= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV60189581; called by muse, mutect2, varscan2
- TUSC3 | c.1028+310G>A | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs369619844; called by muse, varscan2
